Somatic mutation profile of tumor specimen MBCProject_0004_T1_WES (aliquot MBCProject_0004_T1_WES_1) from CMI case MBCProject_0004, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 58.2 years (21,242 days).
Specimen MBCProject_0004_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0bbe3f3-6574-4437-8927-0f7f9f278f6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0004_SALIVA (Saliva), aliquot MBCProject_0004_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30226b3f-072b-4012-8785-a882a207ab4f

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Splice Site 2, Frame Shift Ins 2, Intron 2, Nonsense Mutation 1, 5'Flank 1, In Frame Del 1, Frame Shift Del 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.531+1G>A p.X177_splice | Splice Site (SNP) | VAF 23/69 reads (33%) | hotspot (GDC flag); catalogued as rs1131690808, COSV55728459; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABHD15 | c.47_55del p.A16_L18del | In Frame Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs769564086; called by mutect2, pindel
- ASXL1 | c.3274G>T p.V1092L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV60102471; called by muse, mutect2, varscan2
- CTSK | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs747914097, CM166936, COSV55011355; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCBLD1 | c.1924G>A p.V642I | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs1021792486, COSV99757670; called by muse, mutect2, varscan2
- ERBB2 | c.937C>G p.L313V | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.43); catalogued as COSV54067264; called by muse, mutect2, varscan2
- HDGFL2 | c.677del p.K226Rfs*45 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs1219916331, COSV56682191; called by mutect2, varscan2
- HELLS | c.617A>G p.N206S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs1308854161, COSV53294641; called by muse, mutect2, varscan2
- KMT2C | c.13320T>G p.Y4440* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV51447456; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs768339614, COSV99571588; called by muse, mutect2, varscan2
- NCAPD3 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1363708099, COSV73258381; called by muse, mutect2, varscan2
- NEFH | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs186355000; called by muse, mutect2, varscan2
- FMNL3 | c.1319T>G p.I440S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- GOLM1 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- GSE1 | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- PHACTR4 | c.35C>G p.T12S (on ENST00000373839 / NM_001350159.2; = p.T22S on NM_023923.4) | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- PRRC2B | c.6514G>T p.A2172S | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RIPK1 | c.456_459+9del p.X152_splice | Splice Site (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel
- TACC2 | c.4977A>T p.E1659D | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2
- TBX3 | c.347_348insA p.F116Lfs*22 | Frame Shift Ins (INS) | VAF 45/221 reads (20%) | called by pindel, varscan2
- TBX3 | c.303dup p.D102Rfs*9 | Frame Shift Ins (INS) | VAF 14/155 reads (9%) | called by pindel, varscan2
- ARID2 | c.5070C>T p.H1690= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs1262038394; called by muse, mutect2, varscan2
- NUDT16L1 | c.147G>C p.S49= | Silent (SNP) | VAF 36/190 reads (19%) | catalogued as rs371654760; called by muse, mutect2, varscan2
- OR2B11 | c.357G>A p.L119= | Silent (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- PARD6B | c.873C>T p.S291= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as rs781637858, COSV65404416; called by muse, mutect2, varscan2
- VOPP1 | c.225C>T p.C75= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs776114643; called by muse, mutect2, varscan2
- AC068587.7 | chr8:12659671 del T | 5'Flank (DEL) | VAF 7/62 reads (11%) | catalogued as rs761636901; called by mutect2, pindel
- FMR1 | c.-10T>G | 5'UTR (SNP) | VAF 33/120 reads (28%) | called by muse, mutect2, varscan2
- FRMD8P1 | n.751C>T | RNA (SNP) | VAF 10/20 reads (50%) | catalogued as rs776750375; called by muse, mutect2, varscan2
- REEP6 | c.348+34C>T | Intron (SNP) | VAF 4/35 reads (11%) | catalogued as rs1253335446; called by muse, mutect2
- ZNF710 | c.1825+194G>T | Intron (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
